Gene-level copy-number profile of tumor specimen TCGA-4H-AAAK-01A from TCGA case TCGA-4H-AAAK, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 50.3 years (18,371 days).
Specimen TCGA-4H-AAAK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.1d102fff-6466-491d-9727-9f059aad616f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-4H-AAAK-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7b3a9543-d2b0-481f-a3a1-b852bf5ad68f

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 9; copy number 2: 4,260; copy number 3: 3,748; copy number 4: 43,363; copy number 5: 6,403; copy number 6: 112; copy number 8: 1,504; copy number 12: 415.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-4H-AAAK-01A-12D-A41E-01): tumor purity 0.47, ploidy 3.99, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 415 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr19:11,639,754–11,686,569, 1 gene, copy number 12 (within-gene range 8–12): AC008543.1.
- chr19:11,666,069–14,118,084, 155 genes, copy number 12 (within-gene range 8–12) (broad region; genes not listed).
- chr19:16,719,847–21,801,266, 259 genes, copy number 12 (within-gene range 8–12) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 9. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
